Somatic mutation profile of tumor specimen TCGA-28-1755-01A (aliquot TCGA-28-1755-01A-01W-0643-08) from TCGA case TCGA-28-1755, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.7 years (19,263 days).
Specimen TCGA-28-1755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46dbd757-15b3-49ed-8fdd-f5124b81295e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1755-10A (Blood Derived Normal), aliquot TCGA-28-1755-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04acaaaf-3c93-4014-afcb-741e5252b563

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 2, RNA 2, Intron 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.2578T>A p.Y860N | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV99900289; called by muse, mutect2, varscan2
- AHR | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54121955; called by muse, mutect2, varscan2
- AKR1C1 | c.562T>C p.C188R | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101080514, COSV101080581; called by muse, mutect2, varscan2
- AOC1 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs1426691898, COSV100710725, COSV62866876; called by muse, mutect2, varscan2
- ARHGEF25 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54087401, COSV99678340; called by muse, mutect2
- ATN1 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.179); catalogued as rs146474196; called by muse, mutect2
- B4GALNT2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs144833149; called by muse, mutect2, varscan2
- BUB1B | c.2850+2T>C p.X950_splice | Splice Site (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99807347; called by muse, mutect2, varscan2
- CLCN5 | c.2077C>G p.L693V | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100260408; called by muse, mutect2, varscan2
- COL18A1 | c.2230C>G p.P744A (on ENST00000359759 / NM_130444.3; = p.P509A on NM_030582.4) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs760373742, COSV100700978; called by muse, varscan2
- CYSTM1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs762600257, COSV99945103; called by muse, mutect2, varscan2
- DCAF11 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58109096; called by muse, varscan2
- DYSF | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as rs767340310, COSV99250664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAVL3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1407899639, COSV63648569; called by muse, mutect2, varscan2
- FAM126B | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs536447606, COSV53773412; called by muse, mutect2, varscan2
- FRMPD4 | c.3325G>T p.A1109S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as COSV101044178; called by muse, mutect2, varscan2
- GZMB | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs140343509; called by muse, mutect2, varscan2
- HIVEP2 | c.6741A>T p.L2247F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99175697; called by muse, mutect2, varscan2
- HTR5A | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs750481084, COSV99840013; called by muse, mutect2, varscan2
- IL36G | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV99381272; called by muse, mutect2, varscan2
- LAMA4 | c.5379A>G p.I1793M (on ENST00000230538 / NM_001105206.3; = p.I1786M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.879); catalogued as COSV100039549; called by muse, mutect2, varscan2
- LILRB2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781553478, COSV100079686; called by muse, mutect2, varscan2
- MRGPRX1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs145122494, COSV100246168; called by muse, mutect2, varscan2
- MRTFB | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100371871; called by muse, mutect2
- NDST3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1469072531, COSV56613877; called by muse, mutect2, varscan2
- NEK9 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV99464560; called by muse, varscan2
- OR2T12 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100528016, COSV58778872; called by muse, mutect2, varscan2
- OR52M1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs776180864, COSV100798622; called by muse, mutect2, varscan2
- OTOP1 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs140788465; called by muse, mutect2, varscan2
- OTUD5 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99332270; called by muse, mutect2, varscan2
- PEAK1 | c.4375G>A p.V1459I | Missense Mutation (SNP) | VAF 111/694 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs768139781, COSV56939069, COSV56943228; called by muse, mutect2, varscan2
- PNLIPRP1 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100724536; called by muse, mutect2, varscan2
- PPIP5K1 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 198/532 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100613553; called by muse, mutect2, varscan2
- PPP1R21 | c.1441G>T p.G481* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99682656; called by muse, mutect2
- PSME4 | c.2221G>T p.G741C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV101122690; called by muse, mutect2
- PTPRT | c.3995T>A p.V1332D | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100630754; called by muse, mutect2, varscan2
- RABEP1 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs971053413, COSV52588749; called by muse, mutect2, varscan2
- SNX12 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV99339954; called by muse, mutect2, varscan2
- ST18 | c.309T>A p.S103R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99391177; called by muse, mutect2, varscan2
- TBC1D20 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV62613236; called by muse, mutect2
- THBS1 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 23/154 reads (15%) | catalogued as COSV99528471; called by muse, varscan2
- TICAM1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99941300; called by muse, mutect2
- TMEM132D | c.1729G>T p.V577L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV101243107; called by muse, mutect2
- FITM2 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by mutect2, varscan2
- PRKCE | c.1000T>C p.S334P | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by mutect2, varscan2
- SMC1A | c.693_695del p.N231_E232delinsK | In Frame Del (DEL) | VAF 54/131 reads (41%) | called by mutect2, pindel, varscan2
- XKR6 | c.1572dup p.D525Rfs*3 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- ABI1 | c.1017G>T p.V339= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV100698109; called by muse, mutect2, varscan2
- ADGRF1 | c.282C>T p.C94= | Silent (SNP) | VAF 18/169 reads (11%) | catalogued as rs1224738760, COSV100982698; called by muse, mutect2
- CEACAM8 | c.627C>T p.D209= | Silent (SNP) | VAF 284/640 reads (44%) | catalogued as rs749937078, COSV54990003; called by muse, mutect2, varscan2
- EPHA10 | c.588C>T p.G196= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs747201808, COSV57624985; called by muse, mutect2, varscan2
- GCNT1 | c.870G>A p.V290= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100946663; called by muse, mutect2, varscan2
- GTF3C1 | c.705C>T p.A235= | Silent (SNP) | VAF 13/388 reads (3%) | catalogued as rs1480134352; called by muse, mutect2
- HTR2C | c.855C>T p.N285= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs782359396, COSV52211534; called by muse, mutect2, varscan2
- ITGAD | c.2397C>T p.N799= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as rs1303308761, COSV66757763, COSV66758857; called by muse, mutect2, varscan2
- OR10W1 | c.600G>A p.V200= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV101223801; called by muse, mutect2, varscan2
- OR2G6 | c.426G>A p.A142= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs754561742, COSV58574602; called by muse, mutect2, varscan2
- OTUD7B | c.1284C>T p.Y428= | Silent (SNP) | VAF 73/181 reads (40%) | catalogued as COSV100967813; called by muse, mutect2, varscan2
- PCDH17 | c.2418C>T p.L806= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV100932092; called by muse, mutect2, varscan2
- PTPN14 | c.1251G>A p.G417= | Silent (SNP) | VAF 178/275 reads (65%) | catalogued as COSV100872962; called by muse, mutect2, varscan2
- RRP1 | c.156G>A p.L52= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV101513892; called by muse, mutect2, varscan2
- MIR548A2 | n.43dup | RNA (INS) | VAF 20/75 reads (27%) | called by mutect2, pindel
- SNORD116-6 | n.92G>A | RNA (SNP) | VAF 134/286 reads (47%) | catalogued as rs1475127439; called by muse, mutect2, varscan2
- TTN | c.10360+2429A>C | Intron (SNP) | VAF 46/107 reads (43%) | catalogued as COSV100600392, COSV100631846; called by muse, mutect2, varscan2
